Somatic mutation profile of tumor specimen TARGET-50-PADXAY-01A (aliquot TARGET-50-PADXAY-01A-01D) from TARGET case TARGET-50-PADXAY, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.4 years (1,958 days).
Specimen TARGET-50-PADXAY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a36c7666-dd5e-4a2b-985e-b53743e84487.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PADXAY-10A (Blood Derived Normal), aliquot TARGET-50-PADXAY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93a55e47-e0f1-4c07-bd1f-ec20e17ea258

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Nonsense Mutation 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 69/71 reads (97%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs375338359, CM098494, COSV52690857, COSV52980226, COSV53438718; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSMD2 | c.4924G>T p.G1642* | Nonsense Mutation (SNP) | VAF 117/261 reads (45%) | catalogued as COSV53897033; called by muse, mutect2, varscan2
- DNM3 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 127/294 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV62455566; called by muse, mutect2, varscan2
- KMT2C | c.12323G>A p.R4108Q | Missense Mutation (SNP) | VAF 284/372 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs749141132, CM1515257, COSV51423599; called by muse, mutect2, varscan2
- ZNF750 | c.34C>G p.P12A | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53959370; called by muse, mutect2, varscan2
- IFT88 | c.997dup p.M333Nfs*16 (on ENST00000319980 / NM_001318493.2; = p.M324Nfs*16 on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 36/260 reads (14%) | called by pindel, varscan2
- OR6K3 | c.522C>T p.P174= (on ENST00000368146; = p.P158= on NM_001005327.2) | Silent (SNP) | VAF 73/137 reads (53%) | catalogued as rs149886388, COSV63745307; called by muse, mutect2, varscan2
